Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A4FB, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A4FB-06A (Metastatic).

Patient: XXXX

Translation of pathology report

Sample

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, NOS C77.9
(per TSS) 10/7/12

Gross Pathology

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 95 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine.

Lymphocytic infiltrates compound approx. 5 percent of the tissue cells.

Diagnosis: Parts of a malignant tumor, consistent with a metastasis of a melanoma.

Source: NCI Genomic Data Commons file 10fa88b6-d121-456a-b6eb-74e627869d25 (TCGA-FS-A4FB.90678CF5-DD46-4D10-8605-0D1D032450A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).